Somatic mutation profile of tumor specimen ALCH-B0EN-TTP1-A (aliquot ALCH-B0EN-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B0EN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,143 days).
Specimen ALCH-B0EN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 872adcad-f500-4342-8236-64dd07deff4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EN-NB1-A (Blood Derived Normal), aliquot ALCH-B0EN-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01bc078d-769a-41a7-913c-c7828851c99f

The open-access MAF lists 61 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 14, Nonsense Mutation 3, Intron 2, 5'UTR 1, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPT4 | c.1438C>A p.R480S | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67922715; called by muse, mutect2
- CFAP74 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV54575108; called by muse, mutect2
- ELMOD1 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 27/503 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56192985; called by muse, mutect2
- IQSEC3 | c.2054G>C p.G685A (on ENST00000538872 / NM_001170738.2; = p.G382A on NM_015232.1) | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV58281566; called by muse, mutect2
- JRK | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV101401192; called by muse, mutect2, varscan2
- NETO1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 14/359 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV55011988; called by muse, mutect2
- PACS2 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.801); catalogued as rs1555414866; called by muse, mutect2, varscan2
- PKD1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs1429021597; called by muse, mutect2
- POLR3A | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 30/679 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM117047; called by muse, mutect2
- PRDM9 | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 130/795 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as COSV57013131, COSV99691429; called by muse, mutect2, varscan2
- PTPRZ1 | c.1394C>A p.T465K | Missense Mutation (SNP) | VAF 19/468 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV66435618; called by muse, mutect2
- SLC23A2 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs759370167; called by muse, mutect2
- SLC25A43 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99474777; called by mutect2, varscan2
- ANK2 | c.10174T>C p.S3392P | Missense Mutation (SNP) | VAF 18/490 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- CACNA1F | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CDC73 | c.897A>T p.K299N | Missense Mutation (SNP) | VAF 38/724 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.274); called by muse, mutect2
- CELF1 | c.1138C>T p.Q380* (on ENST00000358597 / NM_001376422.1; = p.Q376* on NM_006560.4 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/401 reads (3%) | called by muse, mutect2
- CFAP47 | c.8381G>C p.C2794S | Missense Mutation (SNP) | VAF 15/379 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- CHD7 | c.6262C>T p.P2088S | Missense Mutation (SNP) | VAF 204/1214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSF1R | c.2321G>A p.C774Y | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FHL1 | c.252C>A p.D84E | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.06); called by muse, mutect2
- FRMPD4 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 28/839 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.355); called by muse, mutect2
- KCNMB3 | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 44/1006 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NFU1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- ODC1 | c.950A>T p.Y317F | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- OR4C6 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 29/560 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.391); called by muse, mutect2
- PF4V1 | c.303T>G p.H101Q | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2
- PFKFB3 | c.1153G>T p.V385F | Missense Mutation (SNP) | VAF 16/316 reads (5%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- PKD1 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 27/516 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.02); called by muse, mutect2
- PKHD1L1 | c.3619A>G p.T1207A | Missense Mutation (SNP) | VAF 44/661 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2
- POLR3D | c.1184A>G p.H395R | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2
- PTPRC | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- RBAK | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.063); called by muse, mutect2
- RECK | c.1844G>A p.C615Y | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC18B1 | c.1217G>T p.W406L | Missense Mutation (SNP) | VAF 30/744 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- TCEAL6 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 26/375 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM115 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.112); called by muse, mutect2
- TMEM164 | c.125G>C p.S42T | Missense Mutation (SNP) | VAF 33/475 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.057); called by muse, mutect2
- UNC13C | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VBP1 | c.310A>T p.R104* | Nonsense Mutation (SNP) | VAF 28/344 reads (8%) | called by muse, mutect2
- ZNF629 | c.1987A>T p.I663F | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ACER3 | c.15G>T p.A5= | Silent (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- AHNAK2 | c.4713C>A p.G1571= | Silent (SNP) | VAF 45/767 reads (6%) | called by muse, mutect2
- DGUOK | c.222A>G p.T74= | Silent (SNP) | VAF 16/530 reads (3%) | catalogued as rs1327107105; called by muse, mutect2
- F10 | c.1017G>A p.A339= | Silent (SNP) | VAF 26/506 reads (5%) | catalogued as rs764999398, COSV65022078; called by muse, mutect2
- FLRT3 | c.696G>A p.L232= | Silent (SNP) | VAF 29/463 reads (6%) | catalogued as COSV54041639; called by muse, mutect2
- HMCN1 | c.4041A>T p.T1347= | Silent (SNP) | VAF 27/409 reads (7%) | called by muse, mutect2
- NLGN4X | c.375C>T p.P125= | Silent (SNP) | VAF 64/1030 reads (6%) | catalogued as rs1375055916; called by muse, mutect2
- NOD2 | c.1518C>A p.S506= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- PRDM14 | c.102G>T p.P34= | Silent (SNP) | VAF 18/374 reads (5%) | called by muse, mutect2
- RAB5C | c.633C>T p.S211= | Silent (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- RBMXL3 | c.2277C>A p.A759= | Silent (SNP) | VAF 19/258 reads (7%) | called by muse, mutect2
- SLITRK2 | c.1236A>T p.A412= | Silent (SNP) | VAF 13/334 reads (4%) | catalogued as COSV59427900; called by muse, mutect2
- SRGAP1 | c.1759C>T p.L587= | Silent (SNP) | VAF 24/660 reads (4%) | called by muse, mutect2
- TFAP2B | c.1024C>A p.R342= | Silent (SNP) | VAF 88/825 reads (11%) | catalogued as rs780525367, COSV53830070; called by muse, mutect2, varscan2
- AC073310.1 | n.206C>A | RNA (SNP) | VAF 34/476 reads (7%) | called by muse, mutect2
- C4orf50 | c.-1286A>G | 5'UTR (SNP) | VAF 12/269 reads (4%) | called by muse, mutect2
- CARMIL1 | chr6:25279186 C>A | 5'Flank (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- KLF6 | c.*3331G>T | 3'UTR (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- LINC00917 | n.1564+1516C>G | Intron (SNP) | VAF 11/273 reads (4%) | catalogued as rs1258658105; called by muse, mutect2
- MRTO4 | c.28+25C>T | Intron (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2, varscan2
